Somatic mutation profile of tumor specimen TCGA-24-1564-01A (aliquot TCGA-24-1564-01A-01W-0551-08) from TCGA case TCGA-24-1564, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.5 years (24,668 days).
Specimen TCGA-24-1564-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b87ea4d-ae01-45d0-ba23-e772a95d8b13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1564-10A (Blood Derived Normal), aliquot TCGA-24-1564-10A-01W-0551-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ab82223-8154-4194-93e6-04b847c2be8e

The open-access MAF lists 55 somatic variants for this specimen: 45 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 41, Silent 10, Splice Site 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.559+1G>T p.X187_splice | Splice Site (SNP) | VAF 340/507 reads (67%) | hotspot (GDC flag); catalogued as CS137624, COSV52670017, COSV52686439, COSV52695669; called by muse, mutect2, varscan2
- ACE2 | c.1349T>C p.L450P | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53027725; called by muse, mutect2, varscan2
- ACTN2 | c.2248A>G p.I750V | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.419); catalogued as COSV63978341; called by muse, mutect2, varscan2
- ADGRE5 | c.1216A>G p.N406D (on ENST00000242786 / NM_078481.4; = p.N313D on NM_001784.5) | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV54414874; called by muse, mutect2, varscan2
- ALG10 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 70/628 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201276321, COSV56791855; called by muse, mutect2, varscan2
- ANKS4B | c.319A>T p.S107C | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61140332; called by muse, mutect2, varscan2
- AP2B1 | c.1550C>G p.P517R | Missense Mutation (SNP) | VAF 116/317 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51998361, COSV52003545; called by muse, mutect2, varscan2
- ATRNL1 | c.3006G>T p.K1002N | Missense Mutation (SNP) | VAF 22/812 reads (3%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.721); catalogued as COSV100372028, COSV58120915; called by muse, mutect2
- BACE2 | c.462G>T p.W154C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57743827; called by muse, mutect2, varscan2
- BBS5 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54754358; called by muse, mutect2, varscan2
- CACNA2D1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs370389203; called by muse, mutect2, varscan2
- CDCA7L | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100651180; called by muse, mutect2
- CNBD1 | c.148G>C p.G50R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV72917599; called by muse, mutect2, varscan2
- DDR2 | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV100906751, COSV63372252; called by muse, mutect2
- DEFB110 | c.55+1G>A p.X19_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | catalogued as COSV64484911; called by muse, mutect2, varscan2
- FTH1 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV56446645; called by muse, mutect2, varscan2
- GSTA5 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 44/462 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52861334, COSV52863920; called by muse, mutect2
- HEPH | c.70G>T p.A24S (on ENST00000343002; = p.A78S on NM_138737.5) | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV57972419; called by muse, mutect2, varscan2
- INSR | c.2215G>C p.V739L | Missense Mutation (SNP) | VAF 53/315 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV57173422; called by muse, mutect2, varscan2
- KHDRBS2 | c.1043G>T p.R348I | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1465384102, COSV55492751; called by muse, mutect2, varscan2
- KIAA1210 | c.493T>G p.C165G | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV68180280; called by muse, mutect2, varscan2
- LRP1 | c.11045A>G p.N3682S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV54526079; called by muse, mutect2, varscan2
- MUC16 | c.8228C>T p.S2743L | Missense Mutation (SNP) | VAF 130/812 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs371402846, COSV101202463, COSV67448110; called by muse, mutect2, varscan2
- MYH11 | c.2015C>T p.T672M | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs749498320, COSV55545607; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOM2 | c.436T>G p.F146V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV50774954; called by muse, mutect2, varscan2
- NCAPD3 | c.1860G>A p.W620* | Nonsense Mutation (SNP) | VAF 32/237 reads (14%) | catalogued as COSV73258764; called by muse, varscan2
- NLRP2 | c.3149C>A p.P1050H | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV54760479; called by muse, mutect2
- OR14K1 | c.932T>C p.V311A | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV99314968; called by muse, mutect2
- PHOX2B | c.937A>C p.M313L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.012); catalogued as COSV99891552; called by muse, mutect2, varscan2
- PLEKHA6 | c.1981G>A p.G661R | Missense Mutation (SNP) | VAF 63/547 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV55333412, COSV55340331; called by muse, varscan2
- PRR3 | c.538C>G p.H180D | Missense Mutation (SNP) | VAF 41/289 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.951); catalogued as COSV64835559; called by muse, mutect2, varscan2
- PSD4 | c.2402G>A p.R801H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1421244258, COSV55530334; called by muse, mutect2, varscan2
- RHOJ | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 60/380 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs1349759334, COSV57459327; called by muse, mutect2, varscan2
- SLC26A3 | c.880T>G p.F294V | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60642750; called by muse, mutect2, varscan2
- SLC4A8 | c.1333C>G p.L445V | Missense Mutation (SNP) | VAF 53/394 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV60658338; called by muse, mutect2, varscan2
- SLC5A12 | c.1238A>T p.H413L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV101237727; called by muse, mutect2
- SYNJ1 | c.386T>C p.I129T | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59156893; called by muse, mutect2, varscan2
- TAF6 | c.1938dup p.K647Efs*? | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | catalogued as rs1338853479; called by pindel, varscan2
- TLE1 | c.2057T>A p.V686E | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV64723501; called by muse, mutect2, varscan2
- TMPRSS15 | c.2164G>T p.G722W | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53049290; called by mutect2, varscan2
- USP8 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs368365577, COSV56168598; called by muse, varscan2
- VRK2 | c.32T>A p.L11H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60880649; called by muse, mutect2
- ZDBF2 | c.7053T>G p.N2351K | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV100985201; called by muse, mutect2
- ZNF267 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as COSV56256309; called by muse, mutect2, varscan2
- ZSWIM8 | c.4966G>A p.V1656I (on ENST00000605216 / NM_001242487.2; = p.V1661I on NM_015037.3) | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as COSV55214062; called by muse, mutect2, varscan2
- AHNAK | c.429C>T p.L143= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as rs777476730, COSV99948629; called by muse, mutect2
- COLEC11 | c.609C>T p.I203= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs572396920, COSV52597846; called by muse, mutect2, varscan2
- CSMD2 | c.6180C>T p.S2060= | Silent (SNP) | VAF 42/235 reads (18%) | catalogued as rs757818939, COSV53964162; called by muse, mutect2, varscan2
- EPHB1 | c.1641G>A p.A547= | Silent (SNP) | VAF 86/745 reads (12%) | catalogued as rs776531462, COSV101212909, COSV67670208; called by muse, mutect2, varscan2
- MCTP1 | c.2820C>G p.V940= | Silent (SNP) | VAF 33/210 reads (16%) | catalogued as COSV56533924; called by muse, mutect2, varscan2
- NBEA | c.1935C>T p.H645= | Silent (SNP) | VAF 37/192 reads (19%) | catalogued as COSV59823227; called by muse, mutect2, varscan2
- NEBL | c.2406C>T p.D802= | Silent (SNP) | VAF 137/377 reads (36%) | catalogued as rs748203517, COSV65802713; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR52E2 | c.894G>A p.K298= | Silent (SNP) | VAF 32/314 reads (10%) | catalogued as COSV58613609; called by muse, mutect2
- SDK2 | c.3945G>A p.T1315= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs751976433, COSV66197128; called by muse, mutect2, varscan2
- ZDHHC16 | c.453C>T p.I151= | Silent (SNP) | VAF 18/163 reads (11%) | catalogued as rs199585228, COSV61749782; called by muse, mutect2, varscan2
